Somatic mutation profile of tumor specimen TCGA-DX-A7EN-01A (aliquot TCGA-DX-A7EN-01A-11D-A38Z-09) from TCGA case TCGA-DX-A7EN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 53.6 years (19,588 days).
Specimen TCGA-DX-A7EN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fce207f-40f7-4f60-ad4b-3e6e25b9ca50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EN-11A (Solid Tissue Normal), aliquot TCGA-DX-A7EN-11A-11D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81713e4c-98d3-40cf-9e86-78f3f9471410

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Splice Site 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 37/39 reads (95%) | catalogued as rs137853295, CM920604, COSV57302098, COSV57314492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CENPH | c.191-2A>C p.X64_splice | Splice Site (SNP) | VAF 58/120 reads (48%) | catalogued as COSV99295497; called by muse, mutect2, varscan2
- CEP290 | c.6206C>T p.S2069L | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100468225; called by mutect2, varscan2
- CHL1 | c.1363G>A p.V455M (on ENST00000397491 / NM_001253387.1; = p.V471M on NM_006614.4) | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775477764, COSV56596958, COSV56598034; called by muse, mutect2, varscan2
- DNAH5 | c.1541T>C p.I514T | Missense Mutation (SNP) | VAF 128/170 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV99447461; called by muse, mutect2, varscan2
- DPY19L3 | c.1532C>G p.S511* | Nonsense Mutation (SNP) | VAF 35/65 reads (54%) | catalogued as COSV100639149; called by muse, mutect2, varscan2
- DYNC2H1 | c.11122C>G p.L3708V | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV100518093; called by muse, mutect2, varscan2
- DYRK4 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs371159844; called by muse, mutect2, varscan2
- GOLM1 | c.1004C>G p.A335G | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99974292; called by muse, mutect2, varscan2
- KCNV1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52086753, COSV52088893; called by muse, mutect2, varscan2
- NOS1 | c.3109C>A p.H1037N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100500315; called by muse, mutect2, varscan2
- OR2J3 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV101013599; called by muse, mutect2, varscan2
- OR5B3 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); catalogued as COSV100511954; called by muse, mutect2, varscan2
- PCDH11X | c.3230G>A p.S1077N | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs758063721, COSV100010377; called by muse, mutect2, varscan2
- PORCN | c.904G>T p.V302F (on ENST00000326194 / NM_203475.3; = p.V291F on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100400397; called by muse, mutect2, varscan2
- RIPK4 | c.2278G>A p.A760T (on ENST00000352483; = p.A712T on NM_020639.3) | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.686); catalogued as rs199540981, COSV60186527; called by muse, mutect2, varscan2
- SEC61A2 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100036326; called by muse, mutect2, varscan2
- TIMP2 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs374979973, COSV99430298; called by muse, mutect2, varscan2
- TP53 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs730882003, COSV52761693, COSV52809012, COSV52965683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPH1 | c.391_397+10del p.X131_splice | Splice Site (DEL) | VAF 4/52 reads (8%) | called by mutect2, pindel
- TNFRSF10A | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); called by muse, mutect2
- AFDN | c.5103C>T p.P1701= (on ENST00000447894 / NM_001366320.1; = p.P1658= on NM_001291964.1) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1439127802, COSV100652749; called by muse, mutect2, varscan2
- MCF2L2 | c.1812G>A p.G604= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV100191894; called by muse, mutect2, varscan2
- SYT16 | c.924G>A p.E308= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1280429076, COSV101413545; called by muse, mutect2, varscan2
- ZDHHC16 | c.135C>T p.C45= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as rs759366364, COSV100620529; called by muse, mutect2, varscan2
